Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BQ-01C (Primary Tumor).

1CD-0-3

Carcinoma, Squamous cell, Keratinizing, Nos 8071/3

Site Code: Cervix, Nos C53.9

12/29/10

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Service: Gynecology

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS:

UTERUS, CERVIX; BIOPSY

- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, WITH KERATINIZATION AND NECROSIS (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out [REDACTED] M.D.

Microscopic Description and Comment:

It is not feasible to assess the depth of invasion due to tissue fragmentation and lack of orientation.

History:

The patient is a [REDACTED] year old woman with a cervical mass. Operative procedure: Examination under anesthesia, cervical biopsy.

Specimen(s) Received:

A: CERVIX, CERVICAL BIOPSY

Gross Description

The specimen is received in a single formalin-filled container labeled with the patient's name, [REDACTED] and "cervical biopsy." It consists of five irregular, slightly nodular fragments of red tissue measuring 2.5 x 1.7 x 0.7 cm in aggregate. Labeled A1 and A2. Jar 0.

eks [REDACTED] 9-51

This Surgical Pathology report is available on-line on [REDACTED] and [REDACTED]

The pathologist
and Director
must certify

This report is prepared and its contents are reviewed by the pathologist

This report is prepared and its contents are reviewed by the U.S. Food and Drug Administration

See attached to the report

IHPAA Discrepancy		X
Reviewer Initials: [REDACTED]	Date Reviewed: 12/29/10	

Source: NCI Genomic Data Commons file 4f33bd5e-7ffe-4e6a-8962-445f51d2e4c5 (TCGA-C5-A1BQ.567FBF76-C88B-4D5A-804F-D93C536B2CAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).